TCGA case TCGA-EE-A2MK — Skin Cutaneous Melanoma (TCGA-SKCM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Lymph nodes; Tissue source site: University of Sydney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/47ffe5ef-7d1f-44eb-9307-104771b39381

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Australia; Age at index: 18 years; Vital status: Alive.

Diagnoses (3)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C77.4; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Lymph nodes of inguinal region or leg; Classification of tumor: Progression; Age at diagnosis: 21.4 years (7,834 days); Days to diagnosis: 1,003 days (2.7 years); Prior treatment: No; Days to last follow up: 5,487 days (15.0 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, prior to procurement; Radiation Therapy, NOS, prior to procurement.
2. Malignant melanoma, NOS: Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Clark level: IV; Sites of involvement: Skin, Extremities; Ulceration indicator: No.
   Pathology details: Breslow thickness category: >4.0 mm.
   Recorded as not given: Radiation Therapy, NOS.
3. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 18.7 years (6,831 days); Year of diagnosis: 1999; AJCC staging edition: 5th; AJCC pathologic T: T4a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Melanoma known primary: Yes.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 4,403 days (12.1 years); Disease response: Tumor Free.
- Days to follow up: 4,825 days (13.2 years); Disease response: Tumor Free.
- Days to follow up: 5,487 days (15.0 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 8.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-EE-A2MK-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-EE-A2MK-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT; Initial weight: 120 mg.
  Slide TCGA-EE-A2MK-06A-01-TSA: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 24; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
- Sample TCGA-EE-A2MK-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Breslow thickness at diagnosis: 5.2; Primary melanoma tumor ulceration: No; Primary melanoma mitotic rate: 8; Radiation therapy to primary: No; Primary location: Regional Lymph Node; Primary melanoma skin type: Non-glabrous skin; Prior radiation therapy: No; History neoadjuvant treatment: No.
- Sites of primary melanomas: Primary multiple at diagnosis: No.
- Sites of primary melanomas, Site: Submitted tumor site: Extremities.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; Subsequent known primaries: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 5,487 days; disease-specific survival: no event (censored), 5,487 days; progression-free interval: no event (censored), 5,487 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-EE-A2MK-06A-11D-A194-01): tumor purity 0.77, ploidy 2.67, whole-genome doublings 1.
